Somatic mutation profile of tumor specimen TCGA-AX-A05U-01A (aliquot TCGA-AX-A05U-01A-11W-A027-09) from TCGA case TCGA-AX-A05U, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G1; Age at diagnosis: 56.2 years (20,533 days).
Specimen TCGA-AX-A05U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0fb5602d-b44d-4448-808f-a77e10ce4f26.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A05U-10A (Blood Derived Normal), aliquot TCGA-AX-A05U-10A-01W-A027-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55ce073e-8d80-4487-8351-8bb950edc066

The open-access MAF lists 33 somatic variants for this specimen: 26 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 18, Silent 7, Nonsense Mutation 3, Frame Shift Del 2, Nonstop Mutation 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 37/88 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as rs28931588, COSV62687956, COSV62688134, COSV62688665; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1369_1386del p.Q457_E462del (on ENST00000521381 / NM_181523.3; = p.Q187_E192del on NM_181504.4) | In Frame Del (DEL) | VAF 31/69 reads (45%) | hotspot (GDC flag); catalogued as COSV57138263; called by mutect2, pindel, varscan2
- PTEN | c.209+1_209+2del p.X70_splice | Splice Site (DEL) | VAF 26/66 reads (39%) | hotspot (GDC flag); catalogued as rs1564826836; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 145/478 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARHGAP35 | c.3784C>A p.P1262T | Missense Mutation (SNP) | VAF 79/196 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68335393; called by muse, mutect2, varscan2
- CADM1 | c.337A>G p.N113D | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT tolerated (0.71); PolyPhen benign (0.105); catalogued as COSV59021736; called by muse, mutect2, varscan2
- COL4A1 | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV65431410; called by muse, mutect2, varscan2
- CYB5B | c.388A>G p.I130V | Missense Mutation (SNP) | VAF 40/52 reads (77%) | SIFT tolerated (0.69); PolyPhen benign (0.045); catalogued as rs576407250, COSV57174905; called by muse, mutect2, varscan2
- GREM1 | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 15/32 reads (47%) | catalogued as COSV55716129; called by muse, mutect2, varscan2
- GUCD1 | c.331C>T p.R111W | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs191716304, COSV68035543; called by muse, mutect2, varscan2
- GUCY2F | c.1880C>A p.S627Y | Missense Mutation (SNP) | VAF 34/299 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV54307868; called by muse, mutect2, varscan2
- IL7 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 71/173 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.196); catalogued as COSV55677840; called by muse, mutect2, varscan2
- INPP4A | c.636del p.Y212* | Frame Shift Del (DEL) | VAF 22/54 reads (41%) | catalogued as COSV50786321, COSV50827428; called by mutect2, pindel, varscan2
- NCAM2 | c.391G>C p.D131H | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV53100867; called by muse, mutect2, varscan2
- OR3A3 | c.572C>A p.P191Q | Missense Mutation (SNP) | VAF 74/175 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV52168479; called by muse, mutect2, varscan2
- PATJ | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as rs369818118; called by muse, mutect2, varscan2
- PCCB | c.1619A>C p.*540Sext*37 | Nonstop Mutation (SNP) | VAF 81/194 reads (42%) | catalogued as COSV52447977, COSV99291140; called by muse, mutect2, varscan2
- PTPRK | c.169T>G p.W57G | Missense Mutation (SNP) | VAF 118/282 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63906129; called by muse, mutect2, varscan2
- RERG | c.535C>T p.R179* | Nonsense Mutation (SNP) | VAF 60/119 reads (50%) | catalogued as COSV56999753; called by muse, mutect2, varscan2
- RNASE7 | c.421G>T p.D141Y | Missense Mutation (SNP) | VAF 153/358 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.399); catalogued as COSV53877685; called by muse, mutect2, varscan2
- SLC8A3 | c.811C>T p.R271* | Nonsense Mutation (SNP) | VAF 48/126 reads (38%) | catalogued as rs758701735, COSV63526016; called by muse, mutect2, varscan2
- SRSF4 | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 59/154 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1251650715, COSV65695610; called by muse, mutect2, varscan2
- TAF1L | c.4208C>T p.T1403M | Missense Mutation (SNP) | VAF 203/435 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.24); catalogued as rs778395226, COSV54260622; called by muse, mutect2, varscan2
- ZNF700 | c.419C>A p.S140Y | Missense Mutation (SNP) | VAF 99/216 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV54315085; called by muse, mutect2, varscan2
- ZNF75D | c.769A>C p.K257Q | Missense Mutation (SNP) | VAF 137/340 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV66133420; called by muse, mutect2, varscan2
- KANSL1 | c.442_464del p.A148Wfs*4 | Frame Shift Del (DEL) | VAF 67/209 reads (32%) | called by mutect2, pindel, varscan2
- EXO1 | c.210G>T p.G70= | Silent (SNP) | VAF 33/81 reads (41%) | catalogued as COSV62219550; called by muse, mutect2, varscan2
- EXT1 | c.1134C>T p.A378= | Silent (SNP) | VAF 15/103 reads (15%) | catalogued as rs1201282610, COSV65484408; called by muse, mutect2, varscan2
- FAT3 | c.4095G>A p.P1365= | Silent (SNP) | VAF 53/112 reads (47%) | catalogued as rs762131673, COSV53167376; called by muse, mutect2, varscan2
- NEDD4 | c.2772G>A p.R924= (on ENST00000508342 / NM_001284338.1; = p.R505= on NM_006154.4) | Silent (SNP) | VAF 14/287 reads (5%) | catalogued as COSV100163935; called by muse, mutect2
- NFKBIB | c.636C>T p.H212= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as rs141538336; called by muse, mutect2, varscan2
- P2RY10 | c.318C>T p.C106= | Silent (SNP) | VAF 267/575 reads (46%) | catalogued as rs754221858, COSV50685336; called by muse, mutect2, varscan2
- TRPV3 | c.825C>T p.P275= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as rs372078083; called by muse, mutect2, varscan2
